Somatic mutation profile of tumor specimen 0DKGXF from CCDI case PBBWNF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.8 years (3,202 days).
Specimen 0DKGXF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c24453a-402a-4a4c-bc5d-f484ae5df996.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKGX8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7a4c077-56a6-401d-a9cd-46a12479ae62

The open-access MAF lists 6 somatic variants for this specimen: 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, 5'UTR 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF222 | c.813T>C p.S271= | Silent (SNP) | VAF 43/488 reads (9%) | called by muse, mutect2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 8/52 reads (15%) | catalogued as rs1262556378; called by muse, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- IFI35 | c.120+74A>T | Intron (SNP) | VAF 7/59 reads (12%) | catalogued as rs1210938411; called by muse, mutect2
- NRCAM | c.-57C>A | 5'UTR (SNP) | VAF 16/414 reads (4%) | catalogued as rs926414386, COSV100695372; called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 21/167 reads (13%) | called by muse, varscan2
